Somatic mutation profile of tumor specimen TCGA-63-A5MJ-01A (aliquot TCGA-63-A5MJ-01A-11D-A27K-08) from TCGA case TCGA-63-A5MJ, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB.
Specimen TCGA-63-A5MJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 160b268a-bbd9-4d8f-bf89-08cba17f333b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-63-A5MJ-10A (Blood Derived Normal), aliquot TCGA-63-A5MJ-10A-01D-A27N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d88f71fc-b733-49d1-b269-d108d5966ba5

The open-access MAF lists 199 somatic variants for this specimen: 144 protein-altering or splice-affecting, 53 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 121, Silent 53, Nonsense Mutation 9, Splice Site 7, Frame Shift Ins 3, Frame Shift Del 3, RNA 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.85G>T p.D29Y | Missense Mutation (SNP) | VAF 14/42 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519920, COSV67960002, COSV67960389, COSV67960852; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TNNT2 | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs397516463, CM962587, COSV99372326; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS18 | c.3197C>T p.A1066V | Missense Mutation (SNP) | VAF 63/370 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as rs1163690050, COSV99273280; called by muse, mutect2, varscan2
- ADAMTS3 | c.1706C>A p.T569N | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.735); catalogued as COSV99711375; called by muse, mutect2, varscan2
- AFDN | c.2596A>G p.I866V | Missense Mutation (SNP) | VAF 9/164 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.247); catalogued as COSV100653135; called by muse, mutect2
- AL136295.1 | c.667T>C p.W223R | Missense Mutation (SNP) | VAF 204/437 reads (47%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV99938121; called by muse, mutect2, varscan2
- ALAS1 | c.490A>C p.S164R | Missense Mutation (SNP) | VAF 78/147 reads (53%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV100050372; called by muse, mutect2, varscan2
- ANKRD27 | c.2469C>A p.H823Q | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0.06); catalogued as COSV100042924; called by muse, mutect2, varscan2
- ANKS1B | c.1574A>T p.Q525L | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.932); catalogued as COSV100246322; called by muse, mutect2, varscan2
- ANO5 | c.469G>T p.D157Y | Missense Mutation (SNP) | VAF 53/171 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100201959; called by muse, mutect2, varscan2
- APBA2 | c.1594G>A p.G532S | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as COSV101258182; called by muse, mutect2, varscan2
- ASB4 | c.159G>C p.E53D | Missense Mutation (SNP) | VAF 30/235 reads (13%) | SIFT tolerated (0.84); PolyPhen benign (0.015); catalogued as COSV99987119, COSV99987176; called by muse, mutect2, varscan2
- ATP1A4 | c.1951G>A p.A651T | Missense Mutation (SNP) | VAF 10/137 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.215); catalogued as rs769485753, COSV100927581, COSV63629152; called by muse, mutect2
- BCOR | c.545A>G p.N182S | Missense Mutation (SNP) | VAF 72/116 reads (62%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); catalogued as rs148105564, COSV100653467; called by muse, mutect2, varscan2
- BEND3 | c.37+2T>G p.X13_splice | Splice Site (SNP) | VAF 37/116 reads (32%) | catalogued as COSV100944630; called by muse, mutect2, varscan2
- BMPER | c.731T>C p.V244A | Missense Mutation (SNP) | VAF 13/171 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV99779880; called by muse, mutect2
- BRINP3 | c.790G>A p.A264T | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.59); PolyPhen benign (0.006); catalogued as COSV100819035; called by muse, mutect2, varscan2
- BTG3 | c.623C>T p.P208L | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.981); catalogued as COSV100336322; called by muse, mutect2, varscan2
- C7orf26 | c.213G>T p.E71D | Missense Mutation (SNP) | VAF 64/340 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100253983; called by muse, mutect2, varscan2
- CBFA2T2 | c.508C>A p.L170I | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100656389; called by muse, mutect2, varscan2
- CCDC130 | c.1000G>T p.G334* | Nonsense Mutation (SNP) | VAF 15/60 reads (25%) | catalogued as COSV50004670, COSV99237569; called by muse, mutect2, varscan2
- CDH10 | c.1189A>T p.I397F | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.355); catalogued as COSV100051962; called by muse, mutect2, varscan2
- CDH11 | c.811+2T>A p.X271_splice | Splice Site (SNP) | VAF 21/91 reads (23%) | catalogued as COSV99218852; called by muse, mutect2, varscan2
- CDR2 | c.1160A>G p.K387R | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99193535; called by muse, mutect2, varscan2
- CEP152 | c.1654C>T p.R552C | Missense Mutation (SNP) | VAF 56/127 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.121); catalogued as rs771215715, COSV100358914; called by muse, mutect2, varscan2
- CEP170 | c.3005G>T p.R1002I | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100317294; called by muse, mutect2
- CHD7 | c.454G>C p.V152L | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV101418298; called by muse, mutect2, varscan2
- CLEC14A | c.685G>A p.D229N | Missense Mutation (SNP) | VAF 94/471 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.045); catalogued as COSV100643615; called by muse, mutect2, varscan2
- CNOT4 | c.10A>T p.S4C | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV100211783; called by muse, mutect2, varscan2
- CNTNAP1 | c.2531-2A>G p.X844_splice | Splice Site (SNP) | VAF 82/235 reads (35%) | catalogued as COSV52848634, COSV99226607; called by muse, mutect2, varscan2
- COL14A1 | c.2348C>T p.T783M | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.142); catalogued as rs145606030; called by muse, mutect2, varscan2
- COL22A1 | c.4573C>T p.Q1525* | Nonsense Mutation (SNP) | VAF 35/73 reads (48%) | catalogued as COSV100278983; called by muse, mutect2, varscan2
- CORIN | c.1694C>G p.S565* | Nonsense Mutation (SNP) | VAF 26/78 reads (33%) | catalogued as COSV56687152, COSV56688191; called by muse, mutect2, varscan2
- CRYBG1 | c.1681G>C p.E561Q | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV100954535; called by muse, mutect2, varscan2
- CSMD3 | c.4190C>A p.T1397K (on ENST00000297405 / NM_001363185.1; = p.T1293K on NM_052900.3) | Missense Mutation (SNP) | VAF 18/189 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.985); catalogued as COSV99837828; called by muse, mutect2, varscan2
- DLC1 | c.2388G>T p.K796N (on ENST00000276297 / NM_001348081.2; = p.K359N on NM_006094.5) | Missense Mutation (SNP) | VAF 79/155 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.077); catalogued as COSV99363781; called by muse, mutect2, varscan2
- DYRK1B | c.1009C>G p.L337V | Missense Mutation (SNP) | VAF 37/176 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.2); catalogued as COSV100546647; called by muse, mutect2, varscan2
- DYSF | c.4591A>G p.K1531E | Missense Mutation (SNP) | VAF 173/750 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as COSV99248015; called by muse, varscan2
- GABRG2 | c.1283C>T p.T428I (on ENST00000361925 / NM_001375343.1; = p.T388I on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as COSV100729742; called by muse, mutect2, varscan2
- GOLGB1 | c.4666G>A p.D1556N | Missense Mutation (SNP) | VAF 47/276 reads (17%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as COSV100511112; called by muse, mutect2, varscan2
- GPR158 | c.2176G>T p.E726* | Nonsense Mutation (SNP) | VAF 41/249 reads (16%) | catalogued as COSV100893797, COSV100894176; called by muse, mutect2, varscan2
- GRIN2D | c.605C>T p.S202F | Missense Mutation (SNP) | VAF 86/577 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV99616603; called by muse, mutect2, varscan2
- GRK4 | c.127A>T p.S43C | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.784); catalogued as COSV100584104; called by muse, mutect2, varscan2
- HK2 | c.1142G>T p.R381L | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV51873753, COSV99309207; called by muse, mutect2
- HRH3 | c.1261C>T p.R421W | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372091137, COSV58048340; called by muse, mutect2, varscan2
- ILVBL | c.374G>T p.G125V | Missense Mutation (SNP) | VAF 29/330 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99654929; called by muse, mutect2
- IRF2 | c.806G>A p.R269Q | Missense Mutation (SNP) | VAF 273/424 reads (64%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.92); catalogued as rs553456169, COSV101165841; called by muse, mutect2, varscan2
- ITGA2 | c.3482G>T p.R1161I | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV56856899; called by muse, mutect2
- KANK2 | c.484G>T p.V162L | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0.133); catalogued as rs758504321, COSV100763242; called by muse, mutect2, varscan2
- KCNB2 | c.2184G>T p.Q728H | Missense Mutation (SNP) | VAF 56/610 reads (9%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.518); catalogued as COSV101578843, COSV73050385; called by muse, mutect2
- KCNH7 | c.1638A>C p.E546D | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as COSV100036448; called by muse, mutect2, varscan2
- KCTD8 | c.1219C>G p.R407G | Missense Mutation (SNP) | VAF 130/333 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV100759683, COSV63585505, COSV63589266; called by muse, mutect2, varscan2
- KDM5A | c.1361C>G p.S454C | Missense Mutation (SNP) | VAF 76/459 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); catalogued as COSV101238927; called by muse, mutect2, varscan2
- KIF1B | c.1607A>T p.N536I (on ENST00000377086 / NM_001365952.1; = p.N490I on NM_015074.3) | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99823606; called by muse, mutect2, varscan2
- KNDC1 | c.2500A>T p.S834C | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV100465279; called by muse, mutect2
- LETM2 | c.1104+2C>T p.X368_splice (on ENST00000379957 / NM_001286819.2; = p.X273_splice on NM_144652.3) | Splice Site (SNP) | VAF 23/141 reads (16%) | catalogued as COSV99907473; called by muse, mutect2, varscan2
- LPCAT1 | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 53/93 reads (57%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs775903785, COSV99359075; called by muse, mutect2, varscan2
- LRP2 | c.11842G>C p.D3948H | Missense Mutation (SNP) | VAF 55/201 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99789077; called by muse, mutect2, varscan2
- LRRC66 | c.481A>G p.S161G | Missense Mutation (SNP) | VAF 88/219 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.11); catalogued as COSV100603008; called by muse, mutect2, varscan2
- LRRTM4 | c.1513C>A p.P505T | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.376); catalogued as COSV101297600, COSV69139858; called by muse, mutect2, varscan2
- LY75 | c.4201T>C p.Y1401H | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.2); catalogued as COSV99716611; called by muse, mutect2, varscan2
- LYZ | c.380+2T>C p.X127_splice | Splice Site (SNP) | VAF 20/104 reads (19%) | catalogued as COSV99720156; called by muse, mutect2, varscan2
- MAJIN | c.376G>T p.G126W | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV100104477; called by muse, mutect2, varscan2
- MAP1A | c.1561A>G p.R521G | Missense Mutation (SNP) | VAF 40/142 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100288821; called by muse, mutect2, varscan2
- MC3R | c.481G>T p.A161S | Missense Mutation (SNP) | VAF 75/228 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.766); catalogued as COSV99710668; called by muse, mutect2, varscan2
- MCM8 | c.2241-2A>C p.X747_splice | Splice Site (SNP) | VAF 53/153 reads (35%) | catalogued as rs1447613680, COSV99495823; called by muse, mutect2, varscan2
- MDFIC | c.362G>T p.R121L | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.482); catalogued as COSV99995228; called by muse, mutect2, varscan2
- MUC16 | c.41145C>G p.S13715R | Missense Mutation (SNP) | VAF 38/251 reads (15%) | SIFT tolerated, low confidence (0.22); PolyPhen probably damaging (0.92); catalogued as COSV101109946, COSV66696972; called by muse, mutect2, varscan2
- MYPN | c.733G>A p.A245T | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as COSV100590123; called by muse, mutect2, varscan2
- MYT1L | c.1619C>T p.A540V | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV67732762, COSV67736153; called by muse, mutect2, varscan2
- NEB | c.14214C>A p.I4738= | Splice Region (SNP) | VAF 25/85 reads (29%) | catalogued as rs754491465, COSV99424513; called by muse, mutect2, varscan2
- NEK5 | c.851C>A p.A284E | Missense Mutation (SNP) | VAF 47/87 reads (54%) | SIFT tolerated (0.56); PolyPhen benign (0.057); catalogued as COSV100839254; called by muse, mutect2, varscan2
- NELL1 | c.898G>A p.G300S | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54271098, COSV54295994; called by muse, mutect2, varscan2
- NRG3 | c.1564G>T p.D522Y | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV100931901, COSV64583509; called by muse, mutect2, varscan2
- NXPE4 | c.45G>C p.L15F | Missense Mutation (SNP) | VAF 32/159 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV100970477; called by muse, mutect2, varscan2
- OR10G9 | c.622G>T p.G208C | Missense Mutation (SNP) | VAF 43/261 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.971); catalogued as rs750707868, COSV100901659; called by muse, mutect2, varscan2
- OR2T12 | c.825C>A p.F275L | Missense Mutation (SNP) | VAF 85/337 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as COSV100527835, COSV58778952; called by muse, mutect2, varscan2
- OR2T3 | c.602A>G p.K201R | Missense Mutation (SNP) | VAF 118/558 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); catalogued as COSV100613273; called by muse, mutect2, varscan2
- OR5M8 | c.225T>A p.N75K | Missense Mutation (SNP) | VAF 31/195 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as COSV100510702; called by muse, mutect2, varscan2
- OR5P2 | c.342G>T p.M114I | Missense Mutation (SNP) | VAF 75/209 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100271142; called by muse, mutect2, varscan2
- OR6F1 | c.422C>A p.S141* | Nonsense Mutation (SNP) | VAF 42/174 reads (24%) | catalogued as COSV100129258; called by muse, mutect2, varscan2
- OSTN | c.211C>A p.L71I | Missense Mutation (SNP) | VAF 130/190 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100174251; called by muse, mutect2, varscan2
- OTOGL | c.5670C>G p.Y1890* (on ENST00000547103; = p.Y1881* on NM_173591.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 33/222 reads (15%) | catalogued as COSV100087422; called by muse, mutect2, varscan2
- PAK3 | c.514-2A>T p.X172_splice (on ENST00000262836 / NM_001324328.2; = p.X157_splice on NM_002578.5 and 4 other RefSeq transcripts) | Splice Site (SNP) | VAF 76/120 reads (63%) | catalogued as COSV99457653; called by muse, mutect2, varscan2
- PATL1 | c.1372C>T p.R458C | Missense Mutation (SNP) | VAF 61/151 reads (40%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.981); catalogued as rs753775433, COSV100275026; called by muse, mutect2, varscan2
- PCDHB2 | c.672G>T p.R224S | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.497); catalogued as COSV99523285; called by muse, mutect2, varscan2
- PCDHGB1 | c.395C>G p.A132G | Missense Mutation (SNP) | VAF 71/138 reads (51%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV53897453, COSV99540848; called by muse, mutect2, varscan2
- PDE1A | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as rs747334904, COSV59513247; called by muse, mutect2
- PHACTR2 | c.1557G>C p.R519S | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99991865; called by muse, mutect2, varscan2
- PI15 | c.734G>T p.C245F | Missense Mutation (SNP) | VAF 124/264 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99478091; called by muse, mutect2, varscan2
- PIAS3 | c.1363T>G p.S455A | Missense Mutation (SNP) | VAF 47/336 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as COSV100566809; called by muse, mutect2, varscan2
- PKP4 | c.2458A>T p.M820L | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV100733877; called by muse, mutect2, varscan2
- PPP5C | c.1445C>T p.P482L | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as rs1476326852, COSV99183481; called by muse, mutect2
- PXDN | c.1720A>G p.S574G | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.626); catalogued as COSV99413932; called by muse, mutect2
- RYR2 | c.874G>T p.G292* | Nonsense Mutation (SNP) | VAF 98/315 reads (31%) | catalogued as COSV100771208; called by muse, mutect2, varscan2
- SERPINA10 | c.692T>C p.I231T | Missense Mutation (SNP) | VAF 46/140 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as COSV100003858; called by muse, varscan2
- SLC11A1 | c.301G>A p.V101M | Missense Mutation (SNP) | VAF 82/171 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.15); catalogued as rs900584867, COSV99262187; called by muse, mutect2, varscan2
- SLC8A1 | c.184C>G p.P62A | Missense Mutation (SNP) | VAF 107/247 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100246517; called by muse, mutect2, varscan2
- SMCHD1 | c.5678C>T p.A1893V | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as rs745859698, COSV99861909; called by muse, mutect2, varscan2
- SMG7 | c.2567C>T p.P856L | Missense Mutation (SNP) | VAF 81/195 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.14); catalogued as COSV100750399; called by muse, mutect2, varscan2
- SNAP47 | c.403G>T p.V135F | Missense Mutation (SNP) | VAF 76/198 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100248273, COSV59916733; called by muse, mutect2, varscan2
- SNAPC4 | c.1246G>T p.V416F | Missense Mutation (SNP) | VAF 46/460 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1490039728, COSV100047384; called by muse, mutect2
- SNX27 | c.1366T>G p.C456G | Missense Mutation (SNP) | VAF 147/276 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV100919069; called by muse, mutect2, varscan2
- SOX11 | c.389C>A p.A130D | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as COSV100431244; called by muse, mutect2, varscan2
- SPRY3 | c.191del p.R64Pfs*16 | Frame Shift Del (DEL) | VAF 90/239 reads (38%) | catalogued as COSV57143605; called by mutect2, pindel, varscan2
- SPTBN4 | c.4005C>A p.D1335E | Missense Mutation (SNP) | VAF 34/214 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV100151256; called by muse, mutect2, varscan2
- SSTR1 | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as rs1420083480, COSV57456640, COSV99942938; called by muse, mutect2, varscan2
- STYXL2 | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as COSV99609433; called by muse, mutect2, varscan2
- SUCO | c.2940G>T p.Q980H | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV99743087; called by muse, mutect2, varscan2
- SYNE1 | c.25112A>G p.K8371R (on ENST00000367255 / NM_182961.4; = p.K8323R on NM_033071.3) | Missense Mutation (SNP) | VAF 23/240 reads (10%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV99568850; called by muse, mutect2, varscan2
- TDRD6 | c.5968G>T p.A1990S | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1388486143, COSV100287812; called by muse, mutect2, varscan2
- TIMD4 | c.946C>G p.L316V | Missense Mutation (SNP) | VAF 37/68 reads (54%) | SIFT tolerated (0.23); PolyPhen benign (0.141); catalogued as COSV99192697; called by muse, mutect2, varscan2
- TLR4 | c.2390G>A p.W797* (on ENST00000355622 / NM_138554.5; = p.W757* on NM_003266.4) | Nonsense Mutation (SNP) | VAF 30/226 reads (13%) | catalogued as COSV62923505; called by muse, mutect2, varscan2
- TMEM132D | c.688G>T p.V230L | Missense Mutation (SNP) | VAF 38/158 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as COSV101398364, COSV70598520; called by muse, mutect2, varscan2
- TMEM163 | c.575T>C p.V192A | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99926543; called by muse, mutect2, varscan2
- TNPO1 | c.2614G>T p.V872F | Missense Mutation (SNP) | VAF 32/166 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.037); catalogued as COSV100473641; called by muse, mutect2, varscan2
- TTLL5 | c.3117G>T p.K1039N | Missense Mutation (SNP) | VAF 21/176 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as COSV100090719; called by muse, mutect2, varscan2
- TTN | c.61315G>C p.A20439P (on ENST00000591111; = p.A13015P on NM_003319.4) | Missense Mutation (SNP) | VAF 27/249 reads (11%) | PolyPhen possibly damaging (0.715); catalogued as COSV100618269; called by muse, mutect2, varscan2
- TTN | c.58049G>C p.G19350A (on ENST00000591111; = p.G11926A on NM_003319.4) | Missense Mutation (SNP) | VAF 21/146 reads (14%) | PolyPhen probably damaging (0.999); catalogued as rs368910900; called by muse, mutect2, varscan2
- UGT2B11 | c.410T>C p.M137T | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.314); catalogued as COSV101485258, COSV71424571; called by muse, mutect2, varscan2
- UGT3A1 | c.1503G>T p.W501C | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); catalogued as COSV99954483, COSV99954923; called by muse, mutect2, varscan2
- UNC13D | c.1058A>G p.Q353R | Missense Mutation (SNP) | VAF 71/223 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs763184308, COSV99256963; called by muse, mutect2, varscan2
- USP10 | c.704A>G p.D235G | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as COSV99551522; called by muse, mutect2, varscan2
- XIRP2 | c.8882C>A p.P2961H (on ENST00000628543; = p.P3136H on NM_152381.6) | Missense Mutation (SNP) | VAF 54/196 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV99744204; called by muse, mutect2, varscan2
- ZAR1 | c.1013G>T p.R338L | Missense Mutation (SNP) | VAF 50/297 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs756437431, COSV99906914; called by muse, mutect2, varscan2
- ZFHX4 | c.1882C>G p.L628V | Missense Mutation (SNP) | VAF 9/184 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV50478691; called by muse, mutect2
- ZFPM2 | c.581A>G p.E194G | Missense Mutation (SNP) | VAF 29/262 reads (11%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.994); catalogued as COSV101023281; called by muse, mutect2, varscan2
- ZIM3 | c.420T>A p.Y140* | Nonsense Mutation (SNP) | VAF 91/320 reads (28%) | catalogued as rs545311281, COSV99518235; called by muse, mutect2, varscan2
- ZMYM4 | c.1544C>T p.S515L | Missense Mutation (SNP) | VAF 60/130 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.246); catalogued as COSV100110759; called by muse, mutect2, varscan2
- ZNF133 | c.1471G>A p.E491K (on ENST00000316358 / NM_001352454.2; = p.E490K on NM_003434.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/154 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1023162988, COSV100315538; called by muse, mutect2, varscan2
- ZNF319 | c.1190C>G p.T397S | Missense Mutation (SNP) | VAF 30/236 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV99540247; called by muse, mutect2, varscan2
- ZNF415 | c.1148C>T p.P383L | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV99701694; called by muse, mutect2
- ZNF607 | c.160G>T p.D54Y | Missense Mutation (SNP) | VAF 26/184 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.162); catalogued as COSV100777922; called by muse, mutect2, varscan2
- ZNF782 | c.487C>G p.H163D | Missense Mutation (SNP) | VAF 13/138 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100001446; called by muse, mutect2, varscan2
- ZNF804A | c.2756G>A p.C919Y | Missense Mutation (SNP) | VAF 32/136 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100168552, COSV56472612; called by muse, mutect2, varscan2
- ZNF835 | c.395A>G p.H132R | Missense Mutation (SNP) | VAF 31/215 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101606364; called by muse, mutect2, varscan2
- ARID1A | c.2296dup p.Q766Pfs*51 | Frame Shift Ins (INS) | VAF 60/176 reads (34%) | called by mutect2, pindel, varscan2
- IGKV3D-11 | c.125C>A p.S42Y | Missense Mutation (SNP) | VAF 44/175 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- LILRB3 | c.519C>A p.H173Q | Missense Mutation (SNP) | VAF 48/133 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- MAGI2 | c.699_700del p.E234Gfs*21 | Frame Shift Del (DEL) | VAF 102/351 reads (29%) | called by mutect2, pindel, varscan2
- MID1 | c.937_953del p.I313Lfs*6 | Frame Shift Del (DEL) | VAF 88/171 reads (51%) | called by mutect2, pindel, varscan2
- NEDD4L | c.944_947dup p.Q316Hfs*58 (on ENST00000400345 / NM_001144967.3; = p.Q316Hfs*64 on NM_015277.6) | Frame Shift Ins (INS) | VAF 19/119 reads (16%) | called by mutect2, pindel, varscan2
- RASSF10 | c.1492G>C p.D498H | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF536 | c.1184_1185insT p.L396Pfs*145 | Frame Shift Ins (INS) | VAF 62/184 reads (34%) | called by mutect2, pindel*, varscan2
- ABCB11 | c.2760G>A p.R920= | Silent (SNP) | VAF 31/97 reads (32%) | catalogued as rs774052013, COSV55587167; ClinVar: likely benign; called by muse, mutect2, varscan2
- ACSBG1 | c.1248C>T p.P416= | Silent (SNP) | VAF 36/175 reads (21%) | catalogued as rs773736059, COSV99357554; called by muse, mutect2, varscan2
- ANKRD17 | c.324C>A p.G108= | Silent (SNP) | VAF 29/152 reads (19%) | catalogued as rs201649070, COSV100429459; called by muse, mutect2, varscan2
- APLNR | c.567C>A p.A189= | Silent (SNP) | VAF 34/117 reads (29%) | catalogued as COSV99951509; called by muse, mutect2, varscan2
- ARID4B | c.3324T>C p.H1108= | Silent (SNP) | VAF 77/234 reads (33%) | catalogued as COSV99935796; called by muse, mutect2, varscan2
- AUP1 | c.705A>G p.E235= | Silent (SNP) | VAF 211/517 reads (41%) | catalogued as rs746253272, COSV99239752; called by muse, mutect2, varscan2
- BCL6 | c.510G>A p.R170= | Silent (SNP) | VAF 58/447 reads (13%) | catalogued as rs1272043357, COSV99215812; called by muse, mutect2, varscan2
- BTAF1 | c.5029T>C p.L1677= | Silent (SNP) | VAF 73/232 reads (31%) | catalogued as COSV99795482; called by muse, mutect2, varscan2
- CALCR | c.1099C>T p.L367= (on ENST00000649521 / NM_001164737.2; = p.L351= on NM_001742.4) | Silent (SNP) | VAF 31/80 reads (39%) | catalogued as COSV64011787; called by muse, mutect2, varscan2
- CCDC88C | c.3432G>A p.T1144= | Silent (SNP) | VAF 40/176 reads (23%) | catalogued as rs1179685333, COSV66237856; called by muse, mutect2, varscan2
- CFAP44 | c.504G>T p.L168= | Silent (SNP) | VAF 38/84 reads (45%) | catalogued as COSV99869863; called by muse, mutect2, varscan2
- CHCHD7 | c.9G>T p.S3= (on ENST00000355315 / NM_001011671.3; = p.S15= on NM_024300.4) | Silent (SNP) | VAF 19/134 reads (14%) | catalogued as COSV100374669, COSV57611265; called by muse, mutect2, varscan2
- DDC | c.1419C>T p.D473= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as rs766373242, COSV100779562, COSV63565165; called by muse, mutect2, varscan2
- DPP6 | c.1446C>A p.S482= (on ENST00000377770 / NM_001364500.2; = p.S420= on NM_001936.5) | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as COSV100126232, COSV59599271; called by muse, mutect2, varscan2
- FABP5 | c.168T>A p.T56= | Silent (SNP) | VAF 22/91 reads (24%) | catalogued as COSV99793095; called by muse, mutect2, varscan2
- GGT5 | c.1584C>T p.G528= | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as rs1336113707, COSV99571660; called by muse, mutect2
- GYS2 | c.1326A>G p.P442= | Silent (SNP) | VAF 28/110 reads (25%) | catalogued as rs1314699044, COSV99679883; called by muse, mutect2, varscan2
- HCN1 | c.795C>A p.L265= | Silent (SNP) | VAF 30/105 reads (29%) | catalogued as rs775887697, COSV100300939; called by muse, mutect2, varscan2
- HK2 | c.2724C>G p.A908= | Silent (SNP) | VAF 50/206 reads (24%) | catalogued as COSV99309209; called by muse, mutect2
- HRH3 | c.432C>A p.A144= | Silent (SNP) | VAF 24/93 reads (26%) | catalogued as rs571914991, COSV100420647; called by muse, mutect2, varscan2
- IGHA1 | c.819C>T p.R273= | Silent (SNP) | VAF 39/220 reads (18%) | catalogued as rs778291607; called by muse, mutect2, varscan2
- IGKV1D-17 | c.201G>A p.K67= | Silent (SNP) | VAF 118/429 reads (28%) | called by muse, mutect2, varscan2
- LEFTY2 | c.408G>T p.L136= | Silent (SNP) | VAF 10/17 reads (59%) | catalogued as COSV100832603; called by muse, varscan2
- LTBP2 | c.4296A>G p.T1432= | Silent (SNP) | VAF 65/199 reads (33%) | catalogued as rs1241263925, COSV100000505; called by muse, mutect2, varscan2
- MAGEL2 | c.1962C>A p.P654= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV100046011; called by muse, mutect2, varscan2
- MDN1 | c.12822C>T p.P4274= | Silent (SNP) | VAF 17/80 reads (21%) | catalogued as rs145423323; called by muse, mutect2, varscan2
- NEB | c.14811G>A p.R4937= | Silent (SNP) | VAF 12/87 reads (14%) | catalogued as COSV99424507; called by muse, mutect2, varscan2
- NLRP9 | c.1713T>C p.Y571= | Silent (SNP) | VAF 35/109 reads (32%) | catalogued as COSV100243157; called by muse, mutect2, varscan2
- NOTCH4 | c.5574G>C p.L1858= | Silent (SNP) | VAF 3/24 reads (13%) | catalogued as COSV100900749, COSV66684616; called by muse, mutect2
- OR5AC2 | c.762C>T p.Y254= | Silent (SNP) | VAF 8/88 reads (9%) | catalogued as rs755129719, COSV62279740; called by muse, mutect2
- OR8G5 | c.639C>A p.T213= | Silent (SNP) | VAF 40/246 reads (16%) | catalogued as COSV100422504; called by muse, mutect2, varscan2
- PCDHB13 | c.1692G>A p.P564= | Silent (SNP) | VAF 23/186 reads (12%) | catalogued as rs781808451, COSV53394865; called by muse, mutect2
- PDCL | c.870G>T p.T290= | Silent (SNP) | VAF 23/176 reads (13%) | catalogued as COSV99414153; called by muse, mutect2, varscan2
- PDZD4 | c.1926A>T p.R642= | Silent (SNP) | VAF 86/127 reads (68%) | catalogued as COSV99381435; called by muse, mutect2, varscan2
- PTPRN2 | c.1776C>T p.T592= | Silent (SNP) | VAF 96/538 reads (18%) | catalogued as rs768288918, COSV67058025, COSV67062518; called by muse, mutect2, varscan2
- SEMA5A | c.519C>T p.L173= | Silent (SNP) | VAF 5/81 reads (6%) | catalogued as COSV101228484; called by muse, mutect2
- SIGLECL1 | c.99C>A p.P33= | Silent (SNP) | VAF 29/184 reads (16%) | catalogued as rs758744287, COSV100323952; called by muse, mutect2, varscan2
- SIPA1L3 | c.1464G>T p.R488= | Silent (SNP) | VAF 34/107 reads (32%) | catalogued as rs201902767, COSV55909871; called by muse, mutect2, varscan2
- SLC28A3 | c.78T>G p.L26= | Silent (SNP) | VAF 30/82 reads (37%) | catalogued as COSV100883272; called by muse, mutect2, varscan2
- SORCS1 | c.897T>A p.S299= | Silent (SNP) | VAF 26/100 reads (26%) | catalogued as COSV99547705; called by muse, mutect2, varscan2
- SULF1 | c.1017T>A p.R339= | Silent (SNP) | VAF 189/479 reads (39%) | catalogued as COSV99483376, COSV99484243; called by muse, mutect2, varscan2
- SVIL | c.6576G>A p.T2192= (on ENST00000355867 / NM_021738.3; = p.T1766= on NM_003174.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 25/178 reads (14%) | catalogued as rs550416170, COSV100881346; called by muse, mutect2, varscan2
- TECTA | c.1068C>A p.S356= | Silent (SNP) | VAF 45/246 reads (18%) | catalogued as COSV99880272; called by muse, mutect2, varscan2
- TET3 | c.1623A>G p.E541= | Silent (SNP) | VAF 15/99 reads (15%) | catalogued as COSV99996414; called by muse, mutect2, varscan2
- TGM2 | c.1521C>A p.L507= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV100821668, COSV63932272; called by muse, mutect2, varscan2
- THSD7A | c.3726T>C p.N1242= | Silent (SNP) | VAF 26/86 reads (30%) | catalogued as COSV101439761; called by muse, mutect2, varscan2
- TRIM49 | c.1089A>G p.K363= | Silent (SNP) | VAF 14/160 reads (9%) | catalogued as rs560492199; called by muse, mutect2
- TTC17 | c.2748C>T p.I916= | Silent (SNP) | VAF 21/104 reads (20%) | catalogued as rs762677772, COSV50005903; called by muse, mutect2, varscan2
- UBC | c.780C>T p.D260= | Silent (SNP) | VAF 36/404 reads (9%) | catalogued as rs775159064, COSV60058402; called by muse, mutect2
- USP32 | c.627A>G p.Q209= | Silent (SNP) | VAF 33/130 reads (25%) | catalogued as COSV100342232; called by muse, mutect2, varscan2
- ZBTB44 | c.207G>A p.K69= | Silent (SNP) | VAF 27/152 reads (18%) | catalogued as COSV100777295; called by muse, mutect2, varscan2
- ZIK1 | c.99C>T p.A33= | Silent (SNP) | VAF 37/273 reads (14%) | catalogued as COSV100277537; called by muse, mutect2, varscan2
- ZNF416 | c.1446T>G p.V482= | Silent (SNP) | VAF 15/224 reads (7%) | catalogued as COSV99543862; called by muse, mutect2
- EI24P4 | n.1015C>G | RNA (SNP) | VAF 95/314 reads (30%) | called by muse, mutect2, varscan2
- PKD1L2 | n.4626C>T | RNA (SNP) | VAF 5/32 reads (16%) | catalogued as rs1205852945; called by muse, mutect2
